CPTAC case 01BR031 — Breast — Ductal and Lobular Neoplasms (CPTAC-2)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026), part of the Clinical Proteomic Tumor Analysis Consortium (CPTAC). Disease type: Ductal and Lobular Neoplasms; Primary site: Breast.
https://portal.gdc.cancer.gov/cases/717b4704-523e-4b75-8bc9-24dde2812c8e

Demographics
Sex at birth: female; Race: black or african american; Ethnicity: not hispanic or latino.

Diagnoses (1)
1. Infiltrating duct carcinoma, NOS: ICD-O-3 morphology code: 8500/3; Tissue or organ of origin: Breast, NOS; Age at diagnosis: 61.0 years (22,264 days); AJCC pathologic stage: Stage III; Prior malignancy: no.

Biospecimens (2 samples)
- Sample 107c4d84-cd05-487c-a3aa-bbe849: Sample type: Blood Derived Normal; Tissue type: Normal; Specimen type: Peripheral Blood NOS; Preservation method: Frozen.
- Sample 96c52a27-3d9a-49e7-8ae8-a71e7c: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: Frozen.
